CCDI case PBCEPF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/8648982f-4213-4f19-bbd4-d4ae8d3957ee

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.0 years (6,212 days).

Biospecimens (2 samples)
- Sample 0DQMPN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQMQT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
